Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5196, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5196-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left renal mass.

CGA - BP - 5196

Specimens Submitted:

1: Kidney, left; partial nephrectomy

DIAGNOSIS:

1. Kidney, left; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type ✓

Fuhrman Nuclear Grade:

Nuclear grade II/IV ✓

Tumor Size:

Greatest diameter is 2.8 cm ✓

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Patchy chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "left renal tumor, stitch marks the deepest surgical margin" and consists of a wedge of kidney measuring 4.5 x 4.0 x 3.0 cm. Resection margin is inked black and the specimen is sectioned to reveal a 2.8 x 2.8 x 2.5 cm fleshy and lobulated tumor. The tumor is well-circumscribed, and is 0.5 cm from the inked margin. The renal capsule is grossly intact with a 4.5 x 2.5 x 1.0 cm aggregate of attached fat. A representative section of tumor to margin is frozen for intraoperative consultation. The renal tissue is entirely submitted. A representative section of perinephric fat is submitted.

Summary of sections:

FSC -- frozen section control

K- kidney

F- perinephric fat

Summary of Sections:

Part 1: Kidney, left; partial nephrectomy

Block	Sect. Site	PCs
1	F	1
1	FSC	1
14	K	14

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the Intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Left renal tumor (fs)(axm): Margin negative, favor Renal cell carcinoma.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file 6fda2bf4-0e4f-49a8-af60-c55732ccf7d9 (TCGA-BP-5196.3A401225-55B7-4A41-B747-BCCCC905435F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).